Somatic mutation profile of tumor specimen MP2PRT-PAUSAC-TMP1-A (aliquot MP2PRT-PAUSAC-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUSAC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,849 days).
Specimen MP2PRT-PAUSAC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b322bf15-9d74-47a9-a90a-d0398b972a24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUSAC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUSAC-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78654280-b966-40b1-b4d1-43e20484f912

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Ins 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 72/325 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- SEPTIN9 | c.316C>T p.R106W (on ENST00000427177 / NM_001113491.2; = p.R88W on NM_006640.4) | Missense Mutation (SNP) | VAF 42/738 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs80338761, CM053400; ClinVar: pathogenic; called by muse, mutect2
- CCND3 | c.857A>G p.D286G | Missense Mutation (SNP) | VAF 69/485 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV57829360; called by muse, varscan2
- CRACD | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 152/322 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.197); catalogued as rs1458464761, COSV51715755, COSV99949755; called by muse, varscan2
- GPER1 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 38/650 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201528297; called by muse, mutect2
- GRIN2B | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 71/394 reads (18%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.523); catalogued as rs756224637, COSV74208030; called by muse, mutect2, varscan2
- SLC4A3 | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879409647; called by muse, mutect2
- DDR2 | c.1294-1G>A p.X432_splice | Splice Site (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- DGKB | c.1681A>T p.R561W | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAND1 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 118/256 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.339); called by muse, varscan2
- IGKV2-30 | c.347_348insCAGCGCTGCCGCATGCAAGG p.T117Sfs*? | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | called by mutect2, varscan2
- MST1 | c.2155C>T p.H719Y | Missense Mutation (SNP) | VAF 143/319 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RRAGA | c.205_207del p.F69del | In Frame Del (DEL) | VAF 12/132 reads (9%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.478dup p.R160Pfs*314 | Frame Shift Ins (INS) | VAF 52/545 reads (10%) | called by mutect2, pindel, varscan2
- ZNF345 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DLGAP5 | c.303G>A p.K101= | Silent (SNP) | VAF 69/211 reads (33%) | called by muse, mutect2, varscan2
- LENG8 | c.1392C>T p.G464= | Silent (SNP) | VAF 48/702 reads (7%) | catalogued as rs756247660; called by muse, mutect2
- OR11H1 | c.468A>T p.G156= | Silent (SNP) | VAF 191/523 reads (37%) | catalogued as COSV53271594; called by muse, mutect2, varscan2
